FM case AD3748 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/aa6ee817-4531-4fcd-b942-d8373dec9c26

Female, 61.5 years: Melanoma, NOS (ICD-O-3 8720/3) of the eye; metastasis biopsied or resected from the lymph node. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Metastatic.
